MMRF case MMRF_1795 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/83d2b57a-6f26-4a6a-adf2-25a4647e37ed

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.8 years (27,668 days); ISS stage: III; Days to last known disease status: 1,107 days (3.0 years); Days to last follow up: 1,107 days (3.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1 day.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 392 days (1.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.55 mg/dL; Immunoglobulin G 58.3 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 7 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 182 µmol/L; Blood Urea Nitrogen 19.3 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 11.1 g/dL; Glucose 4.18 mmol/L; C-Reactive Protein 0.087 mg/dL.
- Day 85 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 4.15 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 4.51 mmol/L.
- Day 183 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 3.36 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 7.15 mmol/L.
- Day 274 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 2.93 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 4.28 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 11.4 mmol/L.
- Day 358 (ECOG 2): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 2.12 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 5.9 g/dL; Glucose 8.14 mmol/L.
- Day 429 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 2.35 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 6.66 mmol/L.
- Day 533 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 4.59 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 7.54 mmol/L.
- Day 659 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 7.06 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.83 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 7.59 mmol/L.
- Day 736 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.07 mg/dL; Immunoglobulin G 6.4 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 1.36 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 10 mmol/L.
- Day 820 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.3 mg/dL; Immunoglobulin G 6.14 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 1.48 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 8.75 mmol/L.
- Day 914 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.11 mg/dL; Immunoglobulin G 5.55 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 1.48 g/L; Lactate Dehydrogenase 4.97 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 15.7 mmol/L.
- Day 995 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.5 mg/dL; Immunoglobulin G 5.13 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 1.28 g/L; Lactate Dehydrogenase 5.88 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 11.9 mmol/L.
- Day 1,107 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.3 mg/dL; Immunoglobulin G 6.76 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 4.48 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 14.7 mmol/L.

Other clinical attributes
- Day 1: Weight: 69 kg; Height: 158 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Leukemia.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1795_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1795_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
